Somatic mutation profile of tumor specimen TCGA-P5-A72X-01A (aliquot TCGA-P5-A72X-01A-11D-A32B-08) from TCGA case TCGA-P5-A72X, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 21.7 years (7,913 days).
Specimen TCGA-P5-A72X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e51f8598-a9ea-4190-8e65-b4bb6ebffc0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A72X-10A (Blood Derived Normal), aliquot TCGA-P5-A72X-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae1b426c-138a-49ec-9f4e-c861c454d978

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/63 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 27/57 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs876660825, CM161004, COSV52664064, COSV52987047, COSV53313892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC9 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs781056381, COSV55722209; called by muse, mutect2, varscan2
- ETAA1 | c.1895C>T p.T632I | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.132); catalogued as rs954397282, COSV99712823; called by muse, varscan2
- LNX1 | c.833A>G p.N278S (on ENST00000263925 / NM_001126328.3; = p.N182S on NM_032622.2) | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as rs749983896, COSV99820142; called by muse, mutect2, varscan2
- NUP133 | c.2924A>G p.K975R | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV99773115; called by muse, mutect2, varscan2
- PKN1 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99466510; called by muse, mutect2, varscan2
- TNC | c.4297G>C p.A1433P | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV100405965; called by muse, mutect2, varscan2
- VSIG4 | c.694+1G>T p.X232_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as COSV101038199; called by muse, mutect2
- ATRX | c.5799_5800del p.G1934Efs*7 | Frame Shift Del (DEL) | VAF 141/234 reads (60%) | called by mutect2, pindel, varscan2
- IGHG4 | c.144C>T p.S48= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs367653567; called by muse, mutect2, varscan2
